Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A9TJ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A9TJ-01A (Primary Tumor).

[page 1 of 6]
Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group :

Date of Service: Date Received: Inpatient

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

ICD-O-3

A. PERITONEUM, BIOPSY:

- METASTATIC ADENOCARCINOMA.

Adenocarcinoma NOS 8140/3
Site: Pancreas tail C25.2
p53 5/5/14

B. UMBILICAL NODULE, RESECTION:

- METASTATIC ADENOCARCINOMA.

C. LIVER, LEFT LOBE NODULE, EXCISIONAL BIOPSY:

- METASTATIC ADENOCARCINOMA.

D. PANCREAS, SPLEEN AND LEFT ADRENAL GLAND, RADICAL ANTEGRADE MODULAR PANCREATOSPLENECTOMY:

- INVASIVE PANCREATIC ADENOCARCINOMA, MODERATELY DIFFERENTIATED.

- Size 8.0 cm with direct invasion into left adrenal gland and fibrovascular bundle of splenic hilum.

- Tumor involves wall of stomach (see micro).

- Positive for perineural invasion.

- Suspicious for lymphovascular invasion.

- PANCREATIC MARGIN NEGATIVE FOR MALIGNANCY.

- PANCREATIC INTRAEPITHELIAL NEOPLASIA (PanIN-III).

- ONE BENIGN LYMPH NODE (0/1).

PATHOLOGIC TUMOR STAGING SUMMARY:

Histologic type and grade: Pancreatic adenocarcinoma, Grade 2, moderately differentiated.

Primary tumor: pT3.

Regional lymph nodes: pN0.

Distant metastasis: pM1.

Pathologic stage: IV.

Lymphovascular invasion: Suspicious focus.

Perineural invasion: Positive.

Case #:

Printed:

Page 1

(This report continues... (FINAL))

MR No

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

E. TRANSVERSE MESOCOLON NODULE, RESECTION: - METASTATIC ADENOCARCINOMA.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, June, 2012.

Case 1

Printed:

Page 2

This report continues... (FINAL)

[page 3 of 6]
Patient:

Case #:

Specimen:	Distal pancreas, spleen, left adrenal gland and partial stomach; peritoneal, umbilical, liver, and transverse mesocolon nodules.
Procedure:	Radical antegrade modular pancreaticosplenectomy with local resection of mid transverse mesocolon nodule, left lobe of liver nodule, peritoneal nodule and umbilical implant.
Tumor site:	Distal pancreas.
Tumor size:	8.0 cm.
Histologic type:	Adenocarcinoma.
Histologic grade:	Grade 2, moderate.
Microscopic tumor extension:	Into peripancreatic soft tissue with invasion of left adrenal gland and fibrovascular bundle of splenic hilum; metastasis to stomach, peritoneum, umbilicus, liver and transverse mesocolon.
Margins:	Pancreatic margin negative.
Treatment effect:	Not applicable.
Lymphovascular invasion:	Suspicious focus.
Perineural invasion:	Positive.
Lymph nodes:	One benign peripancreatic lymph node (0/1).
Pathologic tumor staging summary:	
Primary tumor:	pT3.
Regional lymph nodes:	pN0.
Distant metastasis:	pM1.
Pathologic stage:	IV.

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 6]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

Signed by

Source of Specimen:

- A. Peritoneal bx
- B. Umbilical bx
- C. Liver bx
- D. Pancreaticosplenectomy
- E. Transverse mesocolon

Clinical History/Operative Dx:

Pancreatic cancer

Intraoperative Diagnosis:

- A. Peritoneal biopsy (FSA1):
- Adenocarcinoma.
- B. Umbilical nodule, resection (FSB1):
- Adenocarcinoma.

Reported by

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A is designated as peritoneal biopsy. Initially received in the fresh state for frozen section evaluation is a 1.5 x 1.0 x 0.9 cm red-tan nodular piece of soft tissue. The specimen is bisected and one half is submitted for frozen section evaluation. The residual frozen tissue is submitted in A1 for permanent sections and the remaining half is submitted in A2 for routine histology.

B. Part B is designated as umbilical biopsy. Initially received in the fresh state for frozen section evaluation is a lobular and tattered portion of fatty soft tissue measuring 2.5 x 1.5 x 1.0 cm. Sectioning reveals a red-tan nodule, 1.7 x 1.0 x 1.0 cm. One half of the nodule is submitted for frozen section evaluation. The residual frozen tissue is submitted in B1 for permanent sections and the remaining half of the nodule including attached fat is submitted in B2 for routine histology.

C. Part C is designated as liver biopsy. Received in formalin is an irregular fragment of deep tan-brown soft tissue consistent with liver parenchyma, measuring 0.9 x 0.6 x 0.5 cm. The specimen is bisected

Case #:

Printed:

Page 4

This report continues... (FINAL)

MR No

[page 5 of 6]
Patient: [REDACTED]

Case #: [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

revealing a circumscribed, glistening, light gray nodule, 0.4 x 0.3 cm. The specimen is submitted in its entirety between two sponges bisected in C1. [REDACTED]

D. Part D is pancreaticosplenectomy. Initially received in a fresh state for harvesting tissue for [REDACTED] is a pancreaticosplenectomy consisting of spleen, distal pancreas, adrenal gland, and two attached pieces of stomach. The dimensions of the pancreas is difficult to discern due to replacement by tumor that invades the surrounding soft tissue; however, is up to 10.0 cm in length and 4.3 x 1.9 cm.

Sectioning through the stapled proximal margin of resection reveals tan pancreatic parenchyma without gross tumor involvement. Upon sectioning transversely, reveals a well-demarcated tumor mass, grossly 1.8 cm from the pancreatic surgical margin and measuring upwards of 8.0 x 4.3 x 3.5 cm. The tumor mass is dense, light gray and demonstrates obvious involvement into the peripancreatic soft tissue within 0.2 cm of the anterior and posterior radial surfaces. The apparent adrenal gland is slightly distorted, measures upwards of 4.0 x 1.8 x 1.5 cm, and is partially encased and involved by tumor grossly (D11-D12). The remaining length of the pancreas is grossly involved with tumor with the likely distal end of the tail demonstrating poorly visualized lobular, yellow-tan fat and possible pancreatic parenchyma (D9-D10, contiguous sections).

A smaller piece of attached stomach is 4.3 x 1.3 x 0.6 cm, deep red-tan and is incised to reveal prominently wrinkled, deep tan mucosa without gross tumor involvement (D13). A larger wedge-like piece of stomach is 5.9 x 2.0 cm and is red-tan with submucosal tumor involvement (D16). The grossly involved area is greater than 1.0 cm away from the stapled surgical margin. The tumor grossly invades the hilar fat up to the spleen and encasing the splenic vessels. The spleen is 8.7 x 7.6 x 3.3 cm with a glistening, deep purple-tan intact capsule. The spleen is serially sectioned revealing deep red parenchyma without discrete nodularity or grossly invasive tumor component. Lymph nodes searched within the hilar region and superior peripancreatic fat is hindered by tumor replacement. Representative sections are submitted for microscopic evaluation.

Cassette summary:

D1-D2) proximal pancreatic margin of resection, contiguous sections,
D3) proximal end of pancreas and adjacent tumor relationship,
D4-D10) representation of tumor replaced pancreas, submitted in a sequential fashion proximal towards distal end,
D11-D12) adrenal gland - tumor,
D13) small wedge of stomach, surgical margin, submitted,
D14-D15) larger wedge of stomach, surgical margin trimmed and submitted,
D16) stomach wedge with tumor involvement,
D17-D18) spleen with hilum and tumor [REDACTED]

E. Part E is transverse mesocolon biopsy. Received in formalin is a 4 gram piece of lobular and slightly tattered fatty soft tissue, 3.3 x 2.0 x 1.4 cm. A double suture denotes an area of palpable, poorly visualized nodularity. This surface is now marked orange and the remaining margins black. Examination reveals deep yellow-tan, dense nodularity measuring up to 1.1 x 1.0 x 0.7 cm surrounded by glistening, yellow fat. The nodularity is within 0.3 cm of the likely surgical margin (black). The lesion is entirely submitted for

Case #:

Printed:

Page 5

This report continues... (FINAL)

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

microscopic evaluation in E1 and E2 with additional representation of the fat in E3

Microscopic Description:

A. Sections of the peritoneal biopsy show peritoneum with attached skeletal muscle partially involved by metastatic adenocarcinoma forming irregular glands with surrounding desmoplastic stroma. No lymphovascular invasion is identified.

B. Sections of the umbilical nodule show adenocarcinoma involving fibroadipose tissue. The tumor is at the cauterized edge of the fragment. No lymphovascular invasion is identified.

C. Sections of the liver biopsy show a subcapsular focus of metastatic adenocarcinoma. A portion of benign liver tissue is present. No lymphovascular invasion is identified.

D. Sections of the pancreaticosplenectomy show an invasive adenocarcinoma involving the tail of the pancreas. The tumor forms irregular small glands with a surrounding desmoplastic stroma. There is a minor cord and single cell pattern. The nuclei are enlarged with prominent nucleoli and there is cytoplasmic mucin. Perineural invasion is present and there is a focus suspicious for lymphovascular invasion. There are some dilated pancreatic ducts with severe dysplasia and carcinoma in situ. The invasive tumor invades into the surrounding peripancreatic soft tissue with involvement of the left adrenal gland and fibrovascular bundle of the splenic hilum without direct invasion into the splenic parenchyma. The larger wedge of attached stomach has tumor invading through the wall up to the mucosa. It cannot be determined if this focus is due to direct extension or metastatic spread. A single benign peripancreatic lymph node is present. The pancreatic margin is uninvolved.

E. Sections show mesenteric tissue with foci of adenocarcinoma composed of irregular small glands surrounded by desmoplastic stroma. No lymphovascular invasion is identified.

Case #

Printed:

MR No.

Acct No -

Patient Name -

Source: NCI Genomic Data Commons file b86291b2-50f0-496a-a9d5-8ec1083d2f36 (TCGA-HZ-A9TJ.B75112DD-F928-44E2-9379-F38B1E8FDB50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).